Gene-level copy-number profile of tumor specimen ALCH-B4UL-TTP1-A from ALCHEMIST case ALCH-B4UL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 72.6 years (26,520 days).
Specimen ALCH-B4UL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 45a76d11-327f-4a25-8853-67ee3405eb3b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B4UL-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/e268eb06-c343-4b88-b116-99abeeb125cc

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 544; copy number 1: 9,839; copy number 2: 45,598; copy number 3: 2,855; copy number 4: 61; copy number 5: 8; copy number 6: 1.

Homozygous deletions (total copy number 0; autosomes only): 71 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:15,720,312–15,749,896, 4 genes (within-gene range 0–2): AL450998.2, SLC25A34, SLC25A34-AS1, TMEM82.
- chr7:129,770,383–129,785,185, 4 genes: MIR182, MIR96, MIR183, AC084864.1.
- chr8:22,024,125–22,048,809, 2 genes: NPM2, FGF17.
- chr9:40,883,634–40,883,763, 1 gene: AL353626.2.
- chr9:122,742,303–122,828,588, 5 genes: OR1L6, SKA2P1, OR5C1, PDCL, OR1K1.
- chr11:46,380,756–46,386,608, 2 genes: MDK, CHRM4.
- chr11:47,177,522–47,191,542, 3 genes: PACSIN3, MIR6745, AC090589.1.
- chr12:114,657,949–114,767,989, 5 genes: Y_RNA, TBX3, AC026765.3, AC026765.4, AC026765.1.
- chr12:124,529,722–124,542,873, 3 genes (within-gene range 0–2): AC073592.7, AC073592.3, AC073592.9.
- chr12:132,593,031–132,593,698, 1 gene: AC131212.1.
- chr15:25,194,921–25,250,940, 31 genes (within-gene range 0–2): SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44.
- chr15:77,043,680–77,045,160, 1 gene (within-gene range 0–2): AC090181.1.
- chr19:49,015,980–49,036,895, 8 genes (within-gene range 0–2): LHB, AC008687.4, CGB3, AC008687.1, NTF6A, NTF6G, CGB2, CGB1.
- chr22:41,900,944–41,901,012, 1 gene (within-gene range 0–2): MIR33A.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,766,540–143,769,083, 1 gene, copy number 6: FAM91A3P.
- chr11:112,967–207,428, 8 genes, copy number 5 (within-gene range 2–7): AC069287.1, CICP23, LINC01001, AC069287.3, RNU6-447P, BET1L, SCGB1C1, ODF3.

Autosomal genes at a single copy (total copy number 1): 7,461. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
